Somatic mutation profile of cancer-model specimen HCM-CSHL-0809-C54-85A (3D Organoid, passage 10; aliquot HCM-CSHL-0809-C54-85A-01D-A85K-36), derived from the primary tumor of HCMI case HCM-CSHL-0809-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage III; Tumor grade: G3.
Specimen HCM-CSHL-0809-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c24eb059-c48d-4164-a8f1-eec0fc870b62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0809-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0809-C54-11A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61312d0c-e749-4909-81f9-c2b7ada692a0

The open-access MAF lists 78 somatic variants for this specimen: 54 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Nonsense Mutation 5, Frame Shift Del 2, Intron 2, Frame Shift Ins 1, RNA 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 209/454 reads (46%) | catalogued as rs886040985, CM060227; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 203/324 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTN2 | c.1569G>C p.K523N | Missense Mutation (SNP) | VAF 319/695 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63974818; called by muse, mutect2, varscan2
- DDX23 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 411/748 reads (55%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs745628706; called by muse, mutect2, varscan2
- ERN2 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs139033890; called by muse, mutect2, varscan2
- FZD3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 143/328 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.32); catalogued as rs749595498; called by muse, mutect2, varscan2
- HEATR1 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 259/522 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs778570394, COSV63982589; called by muse, mutect2, varscan2
- HOXD4 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 220/438 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV60459549; called by muse, mutect2, varscan2
- MAP3K9 | c.1434C>G p.D478E | Missense Mutation (SNP) | VAF 187/388 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV67121466; called by muse, mutect2, varscan2
- NLGN3 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 94/594 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs768259710, COSV100705169; called by muse, mutect2, varscan2
- OGFOD2 | c.779G>A p.G260D (on ENST00000228922 / NM_001304833.1; = p.G200D on NM_024623.3) | Missense Mutation (SNP) | VAF 291/884 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54907430; called by muse, mutect2, varscan2
- PECR | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 208/422 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99526686; called by muse, varscan2
- PI4K2B | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 69/679 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs116488560; called by muse, mutect2
- PKIG | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 158/588 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.683); catalogued as rs777632031; called by muse, mutect2, varscan2
- RPS5 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 346/839 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV52190978; called by muse, mutect2, varscan2
- RSRC1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 155/308 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs773930659, COSV55827339, COSV99905331; called by muse, mutect2, varscan2
- SHC3 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 190/466 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.725); catalogued as rs142110184; called by muse, mutect2, varscan2
- SLC8B1 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 312/717 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52529512, COSV52531289; called by muse, mutect2, varscan2
- TMEM132D | c.3126G>T p.R1042S | Missense Mutation (SNP) | VAF 320/760 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770471185, COSV67161745; called by muse, mutect2, varscan2
- TP53 | c.654_655insTGG p.V218_P219insW | In Frame Ins (INS) | VAF 8/39 reads (21%) | catalogued as COSV52886268; called by pindel, varscan2*
- AAAS | c.1354G>T p.G452* | Nonsense Mutation (SNP) | VAF 115/531 reads (22%) | called by muse, mutect2, varscan2
- AK9 | c.2905G>T p.A969S | Missense Mutation (SNP) | VAF 173/654 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CLCN1 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 60/1042 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- COL24A1 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 46/668 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.073); called by muse, mutect2
- CPNE4 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 16/606 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2
- DNAH7 | c.4756G>T p.A1586S | Missense Mutation (SNP) | VAF 99/543 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERF | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 38/696 reads (5%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2
- FAM234A | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 305/358 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GIT1 | c.722A>C p.H241P | Missense Mutation (SNP) | VAF 65/621 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GPRC6A | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 140/586 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.817); called by mutect2, varscan2
- GREB1L | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 18/710 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.269); called by muse, mutect2
- HRNR | c.3248C>A p.S1083* | Nonsense Mutation (SNP) | VAF 283/1834 reads (15%) | called by muse, mutect2, varscan2
- ITGAM | c.2731A>G p.T911A (on ENST00000648685 / NM_001145808.2; = p.T910A on NM_000632.4) | Missense Mutation (SNP) | VAF 103/317 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- JAKMIP2 | c.1823T>G p.F608C | Missense Mutation (SNP) | VAF 312/628 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- KIF27 | c.1572G>C p.L524F | Missense Mutation (SNP) | VAF 209/639 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MDC1 | c.1422C>A p.H474Q | Missense Mutation (SNP) | VAF 103/2363 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2
- MEOX2 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 226/524 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTA2 | c.689C>G p.T230S | Missense Mutation (SNP) | VAF 130/693 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MUC16 | c.28849A>G p.R9617G | Missense Mutation (SNP) | VAF 163/840 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MUC17 | c.7501G>A p.E2501K | Missense Mutation (SNP) | VAF 158/748 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2K2 | c.142del p.Q48Sfs*5 (on ENST00000374428; = p.Q19Sfs*5 on NM_205859.2) | Frame Shift Del (DEL) | VAF 215/478 reads (45%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.3007del p.S1003Afs*17 | Frame Shift Del (DEL) | VAF 49/466 reads (11%) | called by mutect2, pindel, varscan2
- PROX1 | c.296dup p.N99Kfs*2 | Frame Shift Ins (INS) | VAF 160/895 reads (18%) | called by mutect2, pindel, varscan2
- PXDN | c.2759A>T p.E920V | Missense Mutation (SNP) | VAF 47/1109 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2
- RORA | c.707T>C p.I236T (on ENST00000335670 / NM_134261.3; = p.I261T on NM_002943.3) | Missense Mutation (SNP) | VAF 133/680 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RYR1 | c.8564A>C p.Y2855S | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); called by mutect2, varscan2
- RYR1 | c.8565C>A p.Y2855* | Nonsense Mutation (SNP) | VAF 101/461 reads (22%) | called by mutect2, varscan2
- SLC25A12 | c.1388G>C p.G463A | Missense Mutation (SNP) | VAF 24/902 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.4); called by muse, mutect2
- SLC7A7 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 39/959 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPEG | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 68/1128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TAAR9 | c.1012A>C p.T338P | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2
- TMEM132D | c.3127A>T p.K1043* | Nonsense Mutation (SNP) | VAF 321/765 reads (42%) | called by muse, mutect2, varscan2
- TNRC6B | c.3292G>C p.D1098H (on ENST00000454349 / NM_001162501.2; = p.D1045H on NM_015088.3) | Missense Mutation (SNP) | VAF 229/496 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC93B1 | c.1618C>A p.R540S | Missense Mutation (SNP) | VAF 390/915 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA13 | c.3183T>G p.T1061= | Silent (SNP) | VAF 219/512 reads (43%) | called by muse, mutect2, varscan2
- ADRB2 | c.273C>T p.A91= | Silent (SNP) | VAF 134/678 reads (20%) | catalogued as rs1263728753; called by muse, mutect2
- CALB2 | c.672G>A p.L224= | Silent (SNP) | VAF 347/349 reads (99%) | catalogued as COSV100226371; called by muse, mutect2, varscan2
- EMSY | c.1701C>A p.I567= | Silent (SNP) | VAF 86/526 reads (16%) | called by muse, mutect2, varscan2
- FLG | c.4386T>C p.T1462= | Silent (SNP) | VAF 30/1150 reads (3%) | called by muse, mutect2
- FUT8 | c.1727A>G p.*576= (on ENST00000360689 / NM_001371534.1; = p.*413= on NM_004480.4) | Silent (SNP) | VAF 18/216 reads (8%) | catalogued as COSV61282570; called by muse, mutect2
- GPR25 | c.42G>A p.A14= | Silent (SNP) | VAF 340/741 reads (46%) | catalogued as rs898619270, COSV100421796; called by muse, mutect2, varscan2
- HMGB4 | c.402G>T p.A134= | Silent (SNP) | VAF 206/801 reads (26%) | called by muse, mutect2, varscan2
- IGSF9 | c.1629C>T p.Y543= (on ENST00000368094 / NM_001135050.2; = p.Y527= on NM_020789.4) | Silent (SNP) | VAF 239/489 reads (49%) | catalogued as rs763614154; called by muse, varscan2
- KCNE5 | c.204C>A p.I68= | Silent (SNP) | VAF 294/1022 reads (29%) | called by mutect2, varscan2
- LBR | c.558A>G p.K186= | Silent (SNP) | VAF 77/715 reads (11%) | called by muse, mutect2, varscan2
- OR1L4 | c.522C>T p.I174= | Silent (SNP) | VAF 86/1194 reads (7%) | catalogued as COSV52341070; called by muse, mutect2
- PCDHGA7 | c.756C>T p.P252= | Silent (SNP) | VAF 91/775 reads (12%) | catalogued as COSV54015935; called by muse, mutect2, varscan2
- PRTFDC1 | c.90G>A p.T30= | Silent (SNP) | VAF 324/680 reads (48%) | catalogued as rs376280434; called by muse, mutect2, varscan2
- SMARCD3 | c.1420C>T p.L474= (on ENST00000262188 / NM_001003801.2; = p.L461= on NM_003078.4) | Silent (SNP) | VAF 432/735 reads (59%) | called by muse, mutect2, varscan2
- SYT10 | c.432C>A p.V144= | Silent (SNP) | VAF 84/1001 reads (8%) | catalogued as rs762636156, COSV57346821; called by muse, mutect2
- TCL1A | c.72C>T p.F24= | Silent (SNP) | VAF 373/808 reads (46%) | catalogued as rs779175388, COSV68085087; called by muse, mutect2, varscan2
- VWF | c.2358C>T p.L786= | Silent (SNP) | VAF 379/790 reads (48%) | catalogued as COSV54639113; called by muse, mutect2, varscan2
- WDR6 | c.2115T>C p.T705= | Silent (SNP) | VAF 417/829 reads (50%) | called by muse, mutect2, varscan2
- ZNF347 | c.1902T>C p.F634= | Silent (SNP) | VAF 20/716 reads (3%) | catalogued as rs1197715940; called by muse, mutect2
- CRTC1 | c.243+1106C>T | Intron (SNP) | VAF 56/863 reads (6%) | catalogued as rs746121895; called by muse, mutect2
- DCHS2 | n.8341A>G | RNA (SNP) | VAF 28/398 reads (7%) | catalogued as rs140682325; called by muse, mutect2
- GPSM1 | c.1207+111C>T | Intron (SNP) | VAF 377/1188 reads (32%) | called by muse, mutect2
- UBE2V2 | c.-1G>C | 5'UTR (SNP) | VAF 166/694 reads (24%) | catalogued as rs140709996; called by muse, varscan2
